National Lung Screening Trial (NLST) participant 112146 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 56 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 36): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: limited CT, but interpretable (excessive quantum mottle or graininess); technique as recorded on the form: 120 kVp, 60 mA, display field of view 33 cm, reconstruction filter GE, other.
- T1 (day 377): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 50 mA, 29 effective mAs, display field of view 37 cm, reconstruction filter GE Bone.
- T2 (day 736): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 60 mA, 35 effective mAs, display field of view 34 cm, reconstruction filter GE Standard / GE Bone.

Abnormalities recorded by the reading radiologist on the CT screens (5 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 2: Emphysema.
- T1 abnormality 1: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 2: Emphysema.
- T2 abnormality 1: Emphysema.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T6; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 2,235, study year T6. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Primary tumour location: right upper lobe, right hilum. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: moderately differentiated (G2). Tumour size on pathology: 33 mm. AJCC 6th edition staging: stage IB (best stage, from pathologic TNM); clinical T1 N0 M0 (stage IA); pathologic T2 N0 M0 (stage IB). AJCC 7th edition staging: stage IB; clinical T1b N0 M0; pathologic T2a N0 M0.

Follow-up
Last known free of lung cancer: day 2,164.
